TCGA case TCGA-ZF-AA5N — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Sheffield. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f78cb4fa-5548-40f8-b71b-663dde47f539

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 62 years; Vital status: Dead; Days to death: 168 days.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,741 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lung, NOS / Bone, NOS.
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 168 days; Disease response: With Tumor.
- ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 168 cm; BMI: 28.7.

Exposures
- Occupation duration years: 10; Occupation type: Finance Professionals.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 1979; Age at onset: 18.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Ovarian Cancer.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZF-AA5N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-ZF-AA5N-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZF-AA5N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZF-AA5N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: retired; Occupation primary: book keeper; Occupation primary chemical exposure: nil to note; Occupation primary industry: law firm; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Anatomic organ subdivision: Wall NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; New tumor event diagnosis indicator: No.
- Metastatic site list: Metastasis site: Lung; Metastasis site: Bone.
- History non muscle invasive blca: Noninvasive bladder history: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 168 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 168 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 168 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZF-AA5N-01A-11D-A42D-01): tumor purity 0.7, ploidy 2.09, whole-genome doublings 0.
